Surgical pathology report (de-identified scan), TCGA case TCGA-33-4586, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-33-4586-01A (Primary Tumor).

TUMOR SITE:
Left lower lobe.

TUMOR SIZE:
Greatest dimension: 8.5 cm.

CONFIDENTIAL

Source: NCI Genomic Data Commons file 3c50ec01-f0a1-4712-af1d-1fb6be81f4b3 (TCGA-33-4586.7FBF4E5B-0EA6-4630-B35F-9AF85414BE08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).